Gene-level copy-number profile of tumor specimen TCGA-24-0979-01A from TCGA case TCGA-24-0979, project TCGA-OV (Ovarian Serous Cystadenocarcinoma). Sex at birth: female; Vital status: Dead; Primary diagnosis: Serous cystadenocarcinoma, NOS; Tissue or organ of origin: Ovary; FIGO stage: Stage IV; Tumor grade: G3; Age at diagnosis: 53.6 years (19,595 days).
Specimen TCGA-24-0979-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-OV.17fad821-42e6-4165-b2ec-55e98864d94b.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-24-0979-10B (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 812 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/c316897e-ddd8-4187-b4a9-f8591b46e425

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 1: 2,800; copy number 2: 23,240; copy number 3: 21,007; copy number 4: 9,547; copy number 5: 1,623; copy number 6: 793; copy number 7: 286; copy number 8: 291; copy number 10: 56; copy number 11: 168.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, sample TCGA-24-0979-01): tumor purity 0.75, ploidy 2.98, whole-genome doublings 1 (call status: legacy_call).

Homozygous deletions (total copy number 0; autosomes only): none.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 3,217 genes in 9 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr3:11,745–14,082,811, 204 genes, copy number 5–6 (within-gene range 2–6) (broad region; genes not listed).
- chr3:113,286,930–114,310,288, 32 genes, copy number 5 (within-gene range 4–5): CFAP44, AC026348.1, AC112128.1, CFAP44-AS1, MIR8076, SPICE1, SIDT1, SIDT1-AS1, MIR4446, RN7SL767P, USF3, NAA50, AC108693.1, AC108693.2, ATP6V1A, GRAMD1C, AC079944.1, AC079944.2, VPS26AP1, AC128687.2, ZDHHC23, CCDC191, AC128687.1, AC128687.3, AC092896.1, QTRT2, H2BP3, DRD3, AC093010.1, FAM214BP1, ZNF80, TIGIT.
- chr3:114,314,501–114,529,452, 4 genes, copy number 5: AC093010.2, MIR568, ZBTB20-AS1, ZBTB20-AS5.
- chr3:156,977,558–198,222,513, 729 genes, copy number 5–6 (broad region; genes not listed).
- chr5:150,166,778–181,342,213, 596 genes, copy number 5 (broad region; genes not listed).
- chr8:40,530,590–145,066,685, 1,617 genes, copy number 5–11 (within-gene range 4–11) (broad region; genes not listed).
- chr13:33,355,206–33,966,558, 7 genes, copy number 5 (within-gene range 4–5): AL139383.1, AL161719.1, AL139081.1, AL139081.2, RFC3, RNU5A-4P, AL161891.1.
- chr19:27,793,431–27,984,984, 1 gene, copy number 5 (within-gene range 4–5): AC006504.5.
- chr19:27,849,635–29,093,031, 27 genes, copy number 5 (within-gene range 4–5): AC006504.2, AC006504.4, AC005357.2, AC006504.6, AC005758.1, AC005357.1, AC010511.1, AC020905.1, AC005580.1, AC093074.1, AC005307.1, AC005394.2, AC005381.1, AC005394.1, AC005616.1, AC079466.2, AC079466.1, AC005524.1, MAN1A2P1, AC007795.1, LINC00906, AC008991.1, AC011524.1, AC011524.2, RNA5SP470, LINC01532, AC011505.1.

Autosomal genes at a single copy (total copy number 1): 2,341. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
